Surgical pathology report (de-identified scan), TCGA case TCGA-DB-5274, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-5274-01A (Primary Tumor).

[page 1 of 2]
al Diagnosis:

Brain, left frontal, biopsy: WHO Grade 3 (of 3) oligoastrocytoma, oligodendroglial dominant (see comment).

Comment: Nodularity and satellitosis are conspicuous.

TCGA-DB-5274

ADDENDA:

1p19q FISH studies performed on previous specimen () demonstrate 1p19q deletion. Studies are not repeated.

[page 2 of 2]
Preliminary Frozen Section Consultation:
Infiltrating glioma measuring 4.0 x 3.2 x 1.8 cm.

Gross Description:

Tissue from the brain (left frontal--8.5 x 7.2 x 2.3 cm)

1 k Summary:

Part A: left frontal craniotomy tumor

- 1 LT FRONTAL BRAIN
- 2 LT FRONTAL BRAIN
- 3 LT FRONTAL BRAIN
- 4 LT FRONTAL BRAIN
- 5 LT FRONTAL BRAIN
- 6 LT FRONTAL BRAIN
- 7 LT FRONTAL BRAIN
- 8 LT FRONTAL BRAIN

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file 483a80e2-23ea-4cbe-8d6d-1628991ac995 (TCGA-DB-5274.E287CEE7-9711-450C-817E-238D8C3978ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).